Somatic mutation profile of tumor specimen TCGA-BG-A187-01A (aliquot TCGA-BG-A187-01A-11D-A12J-09) from TCGA case TCGA-BG-A187, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.0 years (24,099 days).
Specimen TCGA-BG-A187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc008033-4db4-4871-bd63-113bd5bf3c0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A187-10A (Blood Derived Normal), aliquot TCGA-BG-A187-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/849059d6-da4b-4838-b154-ea6fa7ed053d

The open-access MAF lists 90 somatic variants for this specimen: 69 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Nonsense Mutation 5, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 77/196 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 47/86 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1027-16_1034del p.X343_splice | Splice Site (DEL) | VAF 45/114 reads (39%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AATK | c.2545A>C p.S849R (on ENST00000326724 / NM_001080395.3; = p.S746R on NM_004920.2) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58366996; called by muse, mutect2, varscan2
- ACD | c.874del p.H292Tfs*30 (on ENST00000620338; = p.H203Tfs*30 on NM_022914.3) | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as COSV54667465; called by mutect2, pindel, varscan2
- AFMID | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as rs770780731, COSV59976181; called by muse, mutect2, varscan2
- ALX1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.978); catalogued as rs375150228; called by muse, mutect2, varscan2
- AR | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); catalogued as COSV65957243, COSV65963685; called by muse, mutect2, varscan2
- ARHGAP20 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV52811716; called by muse, mutect2, varscan2
- ATP4A | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs769990049, COSV52866484, COSV99382287; called by muse, mutect2, varscan2
- BMS1 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs1044440, COSV65733011, COSV65733435; called by muse, mutect2, varscan2
- BUB1 | c.949A>G p.R317G | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57063740; called by muse, mutect2, varscan2
- CADPS | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs759883423, COSV51880781; called by muse, mutect2, varscan2
- CBX3 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771446834, COSV61761408; called by muse, mutect2, varscan2
- COPG1 | c.1502del p.Q501Rfs*13 | Frame Shift Del (DEL) | VAF 87/247 reads (35%) | catalogued as COSV100135868, COSV59114218; called by mutect2, pindel, varscan2
- COX19 | c.270dup p.*91Mfs*25 | Frame Shift Ins (INS) | VAF 94/278 reads (34%) | catalogued as rs1162519559; called by mutect2, varscan2
- DUSP16 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as rs149400013; called by muse, mutect2, varscan2
- DYRK1A | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117534, COSV58294108; called by muse, mutect2, varscan2
- EFEMP1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370831953; called by mutect2, varscan2
- EIF2S2 | c.886C>G p.R296G | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66621601, COSV66622263; called by muse, mutect2, varscan2
- FANCM | c.5333C>T p.P1778L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1212903067, COSV57501372; called by muse, mutect2, varscan2
- FASN | c.5220C>T p.G1740= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as rs202024354; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBF1 | c.1481C>G p.S494W (on ENST00000586717; = p.S508W on NM_001319193.1) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV59865183; called by muse, mutect2, varscan2
- GFRA1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV62605883; called by muse, mutect2, varscan2
- GINS3 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV58919808; called by muse, mutect2, varscan2
- GPC6 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV65512473; called by muse, mutect2, varscan2
- HOOK1 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV64618959; called by muse, mutect2, varscan2
- HTR3C | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs138533542, COSV59175400; called by muse, mutect2, varscan2
- INO80 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV62738348; called by muse, mutect2, varscan2
- LIN9 | c.847C>T p.L283F (on ENST00000366808 / NM_001270410.2; = p.L228F on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60245170; called by muse, mutect2, varscan2
- LMAN2 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs962089616, COSV57424652; called by muse, mutect2, varscan2
- LRP1 | c.11896G>A p.D3966N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54511777; called by muse, mutect2, varscan2
- MAP7D3 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV60171031; called by muse, mutect2, varscan2
- MAPK4 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as rs774005634, COSV68542248; called by muse, mutect2, varscan2
- MFSD12 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs569176426, COSV61535588; called by mutect2, varscan2
- MYOF | c.2956C>G p.R986G | Missense Mutation (SNP) | VAF 220/372 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs748167650, COSV63700842, COSV63704467; called by muse, mutect2, varscan2
- NBEA | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59773467; called by muse, mutect2, varscan2
- NCAPD3 | c.4468C>T p.R1490* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as rs1228289225, COSV54452944; called by muse, mutect2, varscan2
- NF1 | c.158T>A p.L53* | Nonsense Mutation (SNP) | VAF 63/153 reads (41%) | catalogued as COSV62204304; called by muse, mutect2, varscan2
- NKRF | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58661629; called by muse, mutect2, varscan2
- NLRP14 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.07); catalogued as COSV55067386; called by muse, mutect2, varscan2
- NTRK2 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52853355, COSV52864557; called by muse, mutect2, varscan2
- NYAP2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55997431; called by muse, mutect2, varscan2
- OFD1 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs758712291, COSV60796009; called by muse, mutect2, varscan2
- OR13C8 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58611211; called by muse, mutect2, varscan2
- PANX2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50295878; called by muse, mutect2
- PANX3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.475); catalogued as rs374548170; called by muse, mutect2, varscan2
- PCDHA3 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.41); catalogued as COSV63541787; called by muse, mutect2, varscan2
- PLA2R1 | c.2831T>A p.L944H | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV51778853; called by muse, varscan2
- PRR16 | c.745C>T p.P249S (on ENST00000407149 / NM_001300783.2; = p.P226S on NM_016644.2) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV65399856; called by muse, mutect2, varscan2
- PTEN | c.402_404del p.M134del | In Frame Del (DEL) | VAF 68/247 reads (28%) | catalogued as rs1554898152; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RCN2 | c.882G>T p.L294F | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs770494865, COSV58031396; called by muse, mutect2, varscan2
- RP1 | c.5870C>T p.P1957L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1352879677, COSV55117169; called by muse, mutect2, varscan2
- RYR2 | c.13900G>A p.V4634I | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756310498, COSV63666877; called by muse, mutect2, varscan2
- SECISBP2L | c.2083C>T p.Q695* (on ENST00000559471 / NM_001193489.2; = p.Q650* on NM_014701.4) | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as COSV55934602; called by muse, mutect2, varscan2
- SLC40A1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53723079; called by muse, mutect2, varscan2
- SLITRK5 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756802240, COSV61521011; called by muse, mutect2, varscan2
- STAG1 | c.2980C>A p.Q994K | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV52610323; called by muse, mutect2, varscan2
- SYN1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55981870; called by muse, mutect2, varscan2
- TAAR8 | c.947G>T p.W316L | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51586307; called by muse, mutect2, varscan2
- TIAM1 | c.4306G>A p.V1436M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV54551885; called by muse, mutect2, varscan2
- TRIM8 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56660559; called by muse, mutect2, varscan2
- TTN | c.97532A>T p.H32511L (on ENST00000591111; = p.H25087L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | PolyPhen benign (0.022); catalogued as COSV60074951; called by muse, mutect2, varscan2
- TXNRD2 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs769258408, COSV68692226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF721 | c.902C>T p.A301V (on ENST00000338977; = p.A313V on NM_133474.4) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs375921561, COSV59092846; called by muse, mutect2, varscan2
- ZNF793 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV71324984, COSV99070611; called by muse, mutect2, varscan2
- CHD4 | c.2796dup p.L933Tfs*3 (on ENST00000357008 / NM_001363606.2; = p.L946Tfs*3 on NM_001273.5) | Frame Shift Ins (INS) | VAF 39/102 reads (38%) | called by mutect2, varscan2
- CADM3 | c.369C>T p.L123= (on ENST00000368125 / NM_001127173.3; = p.L157= on NM_021189.5) | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs1557936347, COSV63684168, COSV63686685; called by muse, mutect2, varscan2
- FAT1 | c.10314C>T p.P3438= | Silent (SNP) | VAF 62/123 reads (50%) | catalogued as rs754838144, COSV71674185, COSV71674899; called by muse, mutect2, varscan2
- HPN | c.1233C>T p.S411= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs778519202, COSV52883686; called by muse, mutect2, varscan2
- IRX2 | c.1398C>T p.G466= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1282541469, COSV57411253; called by muse, mutect2, varscan2
- KY | c.894C>A p.T298= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV71017342; called by muse, mutect2, varscan2
- LMO4 | c.279G>A p.S93= | Silent (SNP) | VAF 85/198 reads (43%) | catalogued as rs139992275; called by muse, mutect2, varscan2
- MARK3 | c.57G>C p.T19= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as COSV53510419; called by muse, mutect2, varscan2
- MMP28 | c.1404C>T p.G468= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs746027832; called by muse, mutect2
- NIBAN2 | c.1278G>A p.T426= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs753880584, COSV64824443; called by muse, mutect2, varscan2
- NPHP4 | c.3270C>T p.A1090= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as rs767473811, COSV100977139, COSV65395002; called by muse, mutect2, varscan2
- OR2A2 | c.423G>A p.T141= | Silent (SNP) | VAF 37/220 reads (17%) | catalogued as rs761421065, COSV68871667; called by muse, mutect2, varscan2
- PAPOLB | c.987C>T p.N329= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as rs1279990113, COSV68200294; called by muse, mutect2
- PCDHB3 | c.1347C>T p.P449= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs782743177, COSV50569020, COSV50574942; called by muse, mutect2, varscan2
- PHC2 | c.201G>A p.Q67= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV57104001; called by muse, mutect2, varscan2
- RNF40 | c.438G>C p.L146= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV61214894; called by muse, mutect2, varscan2
- SFMBT2 | c.348G>A p.R116= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV62809803; called by muse, mutect2, varscan2
- STX17 | c.820T>C p.L274= | Silent (SNP) | VAF 84/214 reads (39%) | catalogued as rs111723145; called by muse, varscan2
- TMEM213 | c.219C>A p.I73= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV59475948, COSV59475974; called by muse, mutect2, varscan2
- TSC22D2 | c.489C>T p.R163= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV62622636; called by muse, mutect2, varscan2
- GABRE | c.784+1241G>T | Intron (SNP) | VAF 93/220 reads (42%) | catalogued as rs1416134176, COSV64819753; called by muse, mutect2, varscan2
- POLR3G | c.*111G>A | 3'UTR (SNP) | VAF 119/338 reads (35%) | catalogued as rs140910392; called by muse, mutect2, varscan2
